Somatic mutation profile of tumor specimen TCGA-CS-6290-01A (aliquot TCGA-CS-6290-01A-11D-1705-08) from TCGA case TCGA-CS-6290, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 31.9 years (11,666 days).
Specimen TCGA-CS-6290-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da40714f-30ea-42c6-badc-a284cb5ce495.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CS-6290-10A (Blood Derived Normal), aliquot TCGA-CS-6290-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/047b5e71-e322-4887-ac65-c3b64d848d91

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 18/90 reads (20%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 28/49 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF38 | c.105C>A p.D35E | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV54444047; called by muse, mutect2
- CR2 | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.238); catalogued as rs758938753, COSV65507543; called by muse, mutect2, varscan2
- FOXP1 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV59549241; called by muse, mutect2
- HSPA1L | c.1271C>A p.T424N | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65149329; called by muse, mutect2, varscan2
- KAT14 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66608693; called by muse, mutect2, varscan2
- LGSN | c.922T>C p.F308L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV65727977; called by muse, mutect2, varscan2
- NFKBIZ | c.2003C>A p.A668D | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58201393; called by muse, mutect2
- OR2B6 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 25/157 reads (16%) | catalogued as COSV55129523; called by muse, mutect2, varscan2
- OR5AN1 | c.707C>A p.S236Y | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.951); catalogued as rs1366826714, COSV58322548; called by muse, mutect2
- PIH1D1 | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as rs1285689865, COSV51808066; called by muse, mutect2, varscan2
- TRIP4 | c.1423A>T p.K475* | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as COSV56032303; called by muse, mutect2, varscan2
- XAB2 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1213088798, COSV50345480; called by muse, mutect2, varscan2
- CEP104 | c.2421C>T p.D807= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as rs189791331, COSV65518704; called by muse, mutect2, varscan2
- IL22RA1 | c.1062C>T p.N354= | Silent (SNP) | VAF 50/126 reads (40%) | catalogued as rs1414587161, COSV54629639; called by muse, mutect2, varscan2
- PCSK9 | c.1119C>T p.S373= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs139683719; ClinVar: benign; called by muse, mutect2, varscan2
- UNC45B | c.18G>A p.A6= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs771865990, COSV52098864; called by muse, mutect2, varscan2
